Gene-level copy-number profile of specimen HCM-BROD-0131-C25-85M from HCMI case HCM-BROD-0131-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Age at diagnosis: 55.9 years (20,435 days).
Specimen HCM-BROD-0131-C25-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a60743f6-ba7e-4939-a56c-dc9f43c94579.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0131-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/f5b00bad-b891-442b-8e60-11103807a133

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 1,813; copy number 2: 15,575; copy number 3: 23,787; copy number 4: 12,361; copy number 5: 3,364; copy number 6: 189; copy number 7: 305; copy number 8: 646; copy number 9: 349; copy number 10: 5.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:13,349,265–13,489,176, 5 genes: FGF7P2, ANKRD30BP1, MIR3156-3, GTF2IP2, VN1R8P.
- chr21:13,525,599–13,528,579, 1 gene: SNX19P1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,305 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:104,590,733–138,914,041, 365 genes, copy number 8–9 (broad region; genes not listed).
- chr9:61,190,003–61,666,386, 12 genes, copy number 9: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2.
- chr12:66,767–28,825,831, 714 genes, copy number 7–8 (broad region; genes not listed).
- chr12:29,142,969–29,340,980, 2 genes, copy number 7 (within-gene range 6–7): AC012150.1, FAR2.
- chr12:29,277,397–30,802,602, 21 genes, copy number 7 (within-gene range 6–7): AC009318.4, AC009318.1, AC009318.3, AC009318.2, ERGIC2, OVCH1-AS1, OVCH1, TMTC1, AC009320.1, RPL21P99, AC023511.2, AC023511.1, LINC02386, AC078776.2, RNA5SP356, AC078776.1, AC026371.1, IPO8, CAPRIN2, AC010198.1, LINC00941.
- chr12:30,926,428–34,249,958, 90 genes, copy number 7 (broad region; genes not listed).
- chr20:22,343,693–23,190,419, 20 genes, copy number 7: AL121912.1, AL133464.1, LINC00261, FOXA2, LNCNEF, LINC01747, AL158175.1, KRT18P3, CYB5AP4, AL353132.1, AL049651.1, AL049651.2, SSTR4, THBD, AL118508.3, CD93, LINC00656, AL118508.2, RNA5SP478, AL118508.1.
- chr20:23,564,732–26,251,546, 75 genes, copy number 7–10 (broad region; genes not listed).
- chr21:40,010,999–40,847,158, 6 genes, copy number 8: DSCAM, MIR4760, DSCAM-AS1, AF064863.1, DSCAM-IT1, AF064866.1.

Autosomal genes at a single copy (total copy number 1): 550. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
